Surgical pathology report (de-identified scan), TCGA case TCGA-32-4210, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-4210-01A (Primary Tumor).

[page 1 of 3]
ADDENDUM DISCUSSION:

Approximately 10-25% of the tumor cells demonstrate MGMT expression.

ADDENDUM DIAGNOSIS:**1,2. BRAIN TUMOR, BIOPSY AND RESECTION:**

- GLIOBLASTOMA (WHO GRADE IV).
- 10-25% MGMT IMMUNOREACTIVITY.

Dictated by:

Verified by:

ACCESSION#:

ADDENDUM NEUROPATHOLOGY REPORT**ADDENDUM DISCUSSION:****ADDENDUM SPECIMEN SOURCE:**

1. Please see previous report.
2. Brain tumor

ADDENDUM GROSS DESCRIPTION:

1. Please see previous report.
2. Received in formalin labeled with the patient's name and "brain tumor" are multiple portions of tan-yellow to brown soft tissue ranging in size from 0.5 to 1.5 cm in greatest dimension and aggregating to 2.7 x 2.0 x 1.2 cm. Representative sections are submitted in three cassettes.

ADDENDUM MICROSCOPIC DESCRIPTION:

1. Please see previous report.
2. Microscopic examination reveals an infiltrating high grade glioma. The tumor cells exhibit significant morphologic atypia. They diffusely infiltrate the cortical gray matter. Pseudopalisading necrosis and microvascular proliferation are identified. Mitotic figures are prevalent. The histologic features are consistent with a glioblastoma.

[page 2 of 3]
ADDENDUM NEUROPATHOLOGY RE. JRT

ADDENDUM DIAGNOSIS:
(PROVISIONAL)

1,2. BRAIN TUMOR, BIOPSY AND RESECTION:
- GLIOBLASTOMA (WHO GRADE IV), PENDING MGMT IMMUNOHISTOCHEMISTRY.

CPT: 88307, 88342

Dictated by:
Verified by:

ACCESSION#:

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

Brain tumor

CLINICAL DIAGNOSIS:

Brain mass

GROSS DESCRIPTION:

Received fresh for frozen section are three small portions of tan-red soft tissue aggregating to 0.6 x 0.4 x 0.3 cm. A smear preparation is performed. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

The previously frozen tissue is subsequently submitted for permanent sections.

[page 3 of 3]
NEUROPATHOLOGY REPORT

MICROSCOPIC DESCRIPTION:

Microscopic examination reveals a high grade malignant glial neoplasm. The tumor is markedly hypercellular. The tumor cells exhibit pleomorphic enlarged nuclei with scattered multinucleated and bizarre forms identified. Mitotic figures are prevalent, including creutzfeldt-type mitoses. Review of the frozen section material reveals microfoci of necrosis. The tumor appears diffusely infiltrative. The histologic features are consistent with a glioblastoma.

DIAGNOSIS:

(PROVISIONAL)

BRAIN TUMOR, BIOPSY:

GLIOBLASTOMA, PENDING REVIEW OF ADDITIONAL MATERIAL

CPT: 88307, 88331

Dictated by:
Verified by:

Source: NCI Genomic Data Commons file 8637cb96-6c13-44c9-a4de-bbf40c9df735 (TCGA-32-4210.B807FF3C-4473-4E77-A199-9DF5C894186F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).